Somatic mutation profile of tumor specimen BA2962D (aliquot aq-BA2962D) from BEATAML1.0 case 2558, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monoblastic and monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.5 years (27,573 days).
Specimen BA2962D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd885813-21fa-498b-baa3-f0c5273a7ee6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2578D (Solid Tissue Normal), aliquot aq-BA2578D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84f4bd32-e52e-4f12-9323-37992eac8d07

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.1556G>T p.R519I (on ENST00000502732 / NM_007314.4; = p.R504I on NM_005158.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as COSV61022468; called by muse, mutect2
- SNU13 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV53237787; called by muse, mutect2
- TGFB1 | c.29_31del p.P10del | In Frame Del (DEL) | VAF 4/42 reads (10%) | catalogued as rs779901179; called by mutect2, pindel
- POGLUT2 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKZ | c.93C>G p.P31= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs781738735; called by muse, mutect2, varscan2
- SYT7 | c.215+9050G>T | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- ZBED3 | c.-152-1771G>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
